Gene-level copy-number profile of tumor specimen MP2PRT-PASZNV-TTR1-A from MP2PRT case MP2PRT-PASZNV, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.3 years (1,919 days).
Specimen MP2PRT-PASZNV-TTR1-A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 557d1424-1f7a-4713-8a80-88ab841cc55c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASZNV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/96a274bc-ccdd-4c9b-8771-00aac4f6db17

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 7,613; copy number 2: 49,292; copy number 3: 437; copy number 4: 412; copy number 5: 162; copy number 6: 194; copy number 7: 131; copy number 8: 112; copy number 9: 29.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr11:90,031,106–90,087,131, 7 genes: TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1.
- chr22:18,715,815–18,757,906, 2 genes: PPP1R26P4, FAM230E.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–1): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 628 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,472,566–148,796,325, 78 genes, copy number 8 (broad region; genes not listed).
- chr1:149,345,661–154,351,304, 283 genes, copy number 6–9 (broad region; genes not listed).
- chr1:154,469,772–157,310,655, 149 genes, copy number 5 (broad region; genes not listed).
- chr1:164,343,005–167,791,919, 76 genes, copy number 6 (broad region; genes not listed).
- chr1:170,460,453–171,251,857, 13 genes, copy number 5 (within-gene range 2–5): GORAB-AS1, GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1, BX284613.2, MROH9, BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P.
- chr1:173,931,084–175,335,459, 26 genes, copy number 7 (within-gene range 3–7): RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT, RABGAP1L, AL022400.1, GPR52, BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2, TNN, KIAA0040, AL008626.1, RPS29P4, Z94057.1.
- chr1:184,387,029–184,629,019, 1 gene, copy number 7 (within-gene range 3–7): C1orf21.
- chr1:184,566,511–184,672,166, 2 genes, copy number 7: AL078645.2, AL713852.1.

Autosomal genes at a single copy (total copy number 1): 7,607. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
